CCDI case PBBYSP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5530f434-41f6-4853-8aa2-061a8ce94af5

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,386 days).

Biospecimens (3 samples)
- Sample 0DKSTV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKSVR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKSZC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
